Somatic mutation profile of tumor specimen MMRF_2606_1_BM_CD138pos (aliquot MMRF_2606_1_BM_CD138pos_T1_KHS5U_L12924) from MMRF case MMRF_2606, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.1 years (25,590 days).
Specimen MMRF_2606_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ceb1c3c4-4f46-4f91-8f2a-aec2d4cacf50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2606_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2606_1_PB_WBC_C3_KHS5U_L12925; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41c82e6c-6af4-4695-87f6-34717ea432b6

The open-access MAF lists 114 somatic variants for this specimen: 39 protein-altering or splice-affecting, 20 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 28, Silent 20, Intron 15, 5'Flank 4, 5'UTR 3, RNA 3, Nonsense Mutation 3, Frame Shift Del 2, 3'Flank 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ3 | c.1599del p.K533Nfs*6 | Frame Shift Del (DEL) | VAF 34/94 reads (36%) | catalogued as rs762289015, COSV101196388; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- AGTRAP | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760177353, COSV58668955; called by muse, mutect2, varscan2
- AP1G1 | c.772C>T p.R258* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as rs1428976744, COSV55494305; called by muse, mutect2, varscan2
- CSPG4 | c.2816G>A p.R939Q | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs764298770, COSV100413430, COSV57897391; called by muse, mutect2, varscan2
- EPPK1 | c.4862G>A p.R1621Q | Missense Mutation (SNP) | VAF 127/340 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs782353672, COSV73260891; called by muse, mutect2, varscan2
- FRMD4B | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 115/252 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs759180502; called by muse, mutect2, varscan2
- IGLV3-9 | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 60/98 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs1178186518; called by muse, mutect2, varscan2
- LRGUK | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs747455238; called by muse, mutect2, varscan2
- MAP1A | c.1177C>T p.R393* | Nonsense Mutation (SNP) | VAF 11/179 reads (6%) | catalogued as COSV55807281; called by muse, mutect2
- MICA | c.385A>G p.S129G | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1352250501; called by muse, mutect2, varscan2
- SLF1 | c.2497G>A p.D833N | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1561480621; called by muse, mutect2
- TDRD9 | c.4078G>A p.D1360N | Missense Mutation (SNP) | VAF 103/246 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs150612714; called by muse, mutect2, varscan2
- TLN2 | c.1555C>T p.L519F | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1387297733; called by muse, mutect2, varscan2
- TMPRSS2 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 109/297 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs762108701, COSV59821951, COSV59823893; called by muse, mutect2, varscan2
- USH2A | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs771074875; called by muse, mutect2
- A4GALT | c.570C>G p.Y190* | Nonsense Mutation (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- ADGRF1 | c.2664T>A p.H888Q | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL18A1 | c.2644-1G>A p.X882_splice (on ENST00000359759 / NM_130444.3; = p.X647_splice on NM_030582.4) | Splice Site (SNP) | VAF 53/268 reads (20%) | called by muse, mutect2, varscan2
- COX7A2 | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DOCK1 | c.5356G>A p.E1786K | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FANCB | c.263G>C p.G88A | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- H2BC3 | c.377A>C p.K126T | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- IL20RA | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNA5 | c.845T>C p.L282P | Missense Mutation (SNP) | VAF 82/228 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MCF2L | c.2496G>A p.M832I (on ENST00000375608; = p.M800I on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- MED12L | c.5897G>A p.S1966N | Missense Mutation (SNP) | VAF 66/335 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDCD11 | c.2930C>T p.S977F | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- RIPOR2 | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.928); called by muse, mutect2
- SBNO2 | c.935_936del p.L312Qfs*28 | Frame Shift Del (DEL) | VAF 55/140 reads (39%) | called by mutect2, pindel, varscan2
- SCAF11 | c.1825C>G p.P609A | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- SERPINH1 | c.848A>C p.K283T | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- TENT5C | c.536_538del p.F179_S180delinsC | In Frame Del (DEL) | VAF 46/127 reads (36%) | called by mutect2, pindel, varscan2
- TIMELESS | c.2165A>C p.N722T | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TLN2 | c.6385C>T p.L2129F | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDFY3 | c.5791T>G p.F1931V | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ZFC3H1 | c.556A>T p.S186C | Missense Mutation (SNP) | VAF 76/214 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- ZMYND15 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ZNF229 | c.1961A>G p.K654R | Missense Mutation (SNP) | VAF 98/175 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- ZNF256 | c.1507A>T p.S503C | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.349); called by muse, mutect2
- B4GALT4 | c.1005C>T p.N335= | Silent (SNP) | VAF 312/572 reads (55%) | called by muse, mutect2, varscan2
- BCL11B | c.1239C>A p.P413= (on ENST00000357195 / NM_001282237.2; = p.P342= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/52 reads (12%) | called by mutect2, varscan2
- COG7 | c.1632C>G p.A544= | Silent (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- CYBC1 | c.207C>T p.A69= | Silent (SNP) | VAF 39/118 reads (33%) | catalogued as rs1252688980; called by muse, mutect2, varscan2
- FANCB | c.738G>A p.E246= | Silent (SNP) | VAF 21/113 reads (19%) | called by muse, mutect2, varscan2
- GBX2 | c.462C>T p.F154= | Silent (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- IGLV3-21 | c.189G>T p.V63= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as rs375188340; called by muse, varscan2
- KIAA1549 | c.1449G>A p.T483= | Silent (SNP) | VAF 37/121 reads (31%) | catalogued as rs762691466, COSV54309361; called by muse, mutect2, varscan2
- KIF24 | c.3540G>A p.G1180= | Silent (SNP) | VAF 21/171 reads (12%) | catalogued as rs770302481; called by muse, mutect2, varscan2
- KMT2D | c.186G>A p.P62= | Silent (SNP) | VAF 64/161 reads (40%) | catalogued as rs367774720; called by muse, mutect2, varscan2
- MAP3K6 | c.811C>T p.L271= | Silent (SNP) | VAF 27/93 reads (29%) | called by muse, mutect2, varscan2
- MORC4 | c.573C>T p.I191= | Silent (SNP) | VAF 42/148 reads (28%) | called by muse, mutect2, varscan2
- MSX1 | c.513G>A p.T171= | Silent (SNP) | VAF 144/380 reads (38%) | catalogued as rs1405255802, COSV66947231; called by muse, mutect2, varscan2
- MYO5A | c.3978C>T p.Y1326= | Silent (SNP) | VAF 190/437 reads (43%) | called by muse, mutect2, varscan2
- NRAP | c.1449C>T p.I483= (on ENST00000359988 / NM_001322945.2; = p.I448= on NM_006175.4) | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as rs141308047; ClinVar: likely benign; called by muse, mutect2, varscan2
- NRXN1 | c.51G>A p.S17= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs200631737; called by muse, mutect2, varscan2
- RBM15 | c.2430C>T p.L810= | Silent (SNP) | VAF 61/169 reads (36%) | catalogued as rs1487248079; called by muse, mutect2, varscan2
- RLN2 | c.420C>T p.A140= | Silent (SNP) | VAF 29/381 reads (8%) | catalogued as rs768910313, COSV57731297; called by muse, mutect2
- ZFAT | c.243G>A p.T81= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as rs202113873; called by muse, mutect2, varscan2
- ZNF467 | c.405A>G p.K135= | Silent (SNP) | VAF 36/99 reads (36%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848430 T>C | 5'Flank (SNP) | VAF 68/175 reads (39%) | called by muse, mutect2, varscan2
- ATXN7 | c.*3639A>C | 3'UTR (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- BMP6 | c.*974G>A | 3'UTR (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- CASK | chrX:41516213 C>T | 3'Flank (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- CCDC149 | c.*346C>T | 3'UTR (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- CD81 | c.355-32C>T | Intron (SNP) | VAF 61/134 reads (46%) | called by muse, mutect2, varscan2
- CEP41 | c.98-2230C>G | Intron (SNP) | VAF 27/78 reads (35%) | called by muse, mutect2, varscan2
- CHM | c.*2881G>A | 3'UTR (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- CMYA5 | c.11407+38C>T | Intron (SNP) | VAF 23/109 reads (21%) | catalogued as rs201522128; called by muse, mutect2, varscan2
- DAZL | c.-87G>A | 5'UTR (SNP) | VAF 55/96 reads (57%) | catalogued as rs1218629232, COSV99167528; called by muse, mutect2, varscan2
- DCAF5 | c.879+1333T>C | Intron (SNP) | VAF 21/73 reads (29%) | called by muse, mutect2, varscan2
- DHCR24 | c.1398-77A>G | Intron (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2
- FAM122B | c.*392G>C | 3'UTR (SNP) | VAF 21/77 reads (27%) | called by muse, mutect2, varscan2
- FBXL7 | c.*540T>G | 3'UTR (SNP) | VAF 35/136 reads (26%) | called by muse, mutect2, varscan2
- FMN1 | c.2044-2605C>T | Intron (SNP) | VAF 55/305 reads (18%) | called by muse, mutect2, varscan2
- GABRA2 | c.187+21282C>T | Intron (SNP) | VAF 34/100 reads (34%) | catalogued as rs534966453; called by muse, mutect2, varscan2
- GANAB | c.*522C>T | 3'UTR (SNP) | VAF 46/95 reads (48%) | catalogued as rs746302915; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2811+13C>T | Intron (SNP) | VAF 85/315 reads (27%) | catalogued as rs782695782; called by muse, mutect2, varscan2
- HAP1 | c.*1978C>A | 3'UTR (SNP) | VAF 46/122 reads (38%) | called by muse, mutect2, varscan2
- HPGD | c.421+602G>T | Intron (SNP) | VAF 12/240 reads (5%) | called by muse, mutect2
- KRT15 | chr17:41519106 T>G | 5'Flank (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2, varscan2
- LINC00544 | n.716A>G | RNA (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- LNPK | c.*1940G>T | 3'UTR (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- LZTS1 | c.*1449A>C | 3'UTR (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- MDGA2 | chr14:46839758 T>C | 3'Flank (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2, varscan2
- MEIS3 | c.13-338C>G | Intron (SNP) | VAF 44/227 reads (19%) | catalogued as rs1261009592; called by muse, mutect2, varscan2
- NARF | chr17:82458737 T>C | 5'Flank (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- NINJ2 | c.33+19959G>T | Intron (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- NIPAL1 | c.*3339A>G | 3'UTR (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- NT5E | c.*1440A>T | 3'UTR (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- OTOAP1 | n.1389C>T | RNA (SNP) | VAF 27/192 reads (14%) | called by muse, mutect2, varscan2
- OTX2 | c.*926G>A | 3'UTR (SNP) | VAF 30/68 reads (44%) | catalogued as rs1036526594; called by muse, mutect2, varscan2
- OXTR | c.*2054C>A | 3'UTR (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- PCDH19 | c.*3613C>G | 3'UTR (SNP) | VAF 22/58 reads (38%) | catalogued as rs1373539958; called by muse, mutect2, varscan2
- PCDHB4 | c.*796del | 3'UTR (DEL) | VAF 40/180 reads (22%) | catalogued as rs1212950420; called by mutect2, varscan2
- PNMA6A | c.*629T>C | 3'UTR (SNP) | VAF 29/156 reads (19%) | catalogued as rs1352314416; called by muse, mutect2, varscan2
- PPP1R2P1 | n.462T>G | RNA (SNP) | VAF 40/96 reads (42%) | called by muse, mutect2, varscan2
- PRMT1 | c.90+80A>T | Intron (SNP) | VAF 39/140 reads (28%) | called by muse, mutect2, varscan2
- RAD18 | c.*3305G>A | 3'UTR (SNP) | VAF 30/96 reads (31%) | catalogued as rs979776619; called by muse, mutect2, varscan2
- SHCBP1L | chr1:182953212 C>T | 5'Flank (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- SLAMF1 | c.*821A>G | 3'UTR (SNP) | VAF 31/95 reads (33%) | called by muse, mutect2, varscan2
- SLC7A7 | c.*166T>G | 3'UTR (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- SMAD2 | c.*4986A>T | 3'UTR (SNP) | VAF 32/106 reads (30%) | called by muse, mutect2
- SPANXN2 | c.-439A>C | 5'UTR (SNP) | VAF 131/304 reads (43%) | called by muse, varscan2
- SPPL2B | c.187-123G>A | Intron (SNP) | VAF 16/32 reads (50%) | catalogued as rs991746668; called by muse, mutect2
- SPRY3 | c.*6679T>C | 3'UTR (SNP) | VAF 139/518 reads (27%) | catalogued as COSV100249389; called by muse, mutect2, varscan2
- STAB1 | c.216-101G>A | Intron (SNP) | VAF 10/30 reads (33%) | catalogued as rs887873448; called by muse, mutect2, varscan2
- THEM6 | c.514-81G>A | Intron (SNP) | VAF 11/30 reads (37%) | catalogued as rs934233877; called by muse, mutect2
- TMEM132B | c.*833C>T | 3'UTR (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- TMEM182 | c.*58dup | 3'UTR (INS) | VAF 6/28 reads (21%) | catalogued as rs985662525; called by mutect2, varscan2
- TMEM207 | c.*48C>T | 3'UTR (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- VHL | c.*1250G>A | 3'UTR (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- WHRN | c.-587G>A | 5'UTR (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- ZBTB44 | c.*3666C>T | 3'UTR (SNP) | VAF 9/42 reads (21%) | catalogued as rs974294553; called by muse, mutect2, varscan2
- ZNF587 | c.*2308A>G | 3'UTR (SNP) | VAF 83/276 reads (30%) | catalogued as rs1433315614; called by muse, mutect2, varscan2
